Somatic mutation profile of tumor specimen C3L-00607-01 (aliquot CPT0025050009) from CPTAC case C3L-00607, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 66.6 years (24,311 days).
Specimen C3L-00607-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b52638d7-f25f-478c-8102-aa1a5e61260d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00607-32 (Blood Derived Normal), aliquot CPT0029400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10ce5bc0-4b85-4d6c-89d0-e26185fa9ac8

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Nonsense Mutation 3, Frame Shift Ins 3, Intron 3, Splice Site 2, Frame Shift Del 1, RNA 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD17B4 | c.345del p.F115Lfs*4 (on ENST00000414835 / NM_001199291.3; = p.F90Lfs*4 on NM_000414.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 73/229 reads (32%) | catalogued as rs1276397342; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TTN | c.47934C>A p.C15978* (on ENST00000591111; = p.C8554* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 102/483 reads (21%) | catalogued as rs1057520724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1AR | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); catalogued as COSV56770241; called by muse, mutect2
- ATP1A3 | c.3022C>T p.R1008C (on ENST00000545399 / NM_001256214.2; = p.R995C on NM_152296.5) | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57485526, COSV57486287; called by muse, mutect2, varscan2
- COL22A1 | c.943G>T p.V315F | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs147583696; called by muse, mutect2, varscan2
- CRTAC1 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs750669625; called by muse, mutect2, varscan2
- DNMT3A | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs762563426, COSV53043972, COSV53050639; called by muse, mutect2, varscan2
- DOCK2 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1260020369; called by muse, mutect2, varscan2
- ELMO1 | c.632A>G p.N211S | Missense Mutation (SNP) | VAF 54/406 reads (13%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.456); catalogued as rs774843181; called by muse, mutect2, varscan2
- GPIHBP1 | c.332C>G p.T111R | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs762969345; called by muse, mutect2, varscan2
- IMPDH1 | c.318G>T p.K106N (on ENST00000470772 / NM_001142573.2; = p.K191N on NM_000883.4) | Missense Mutation (SNP) | VAF 104/500 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1165280835; called by muse, mutect2, varscan2
- INSR | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV100251213, COSV57166599; called by muse, mutect2, varscan2
- SPAG5 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs563369968; called by muse, mutect2, varscan2
- TET2 | c.549_550insTT p.E184Lfs*24 | Frame Shift Ins (INS) | VAF 30/128 reads (23%) | catalogued as COSV54407154; called by mutect2, pindel, varscan2
- TMEM145 | c.751T>C p.F251L | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.482); catalogued as rs767338327; called by muse, mutect2, varscan2
- TTBK1 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362388798; called by muse, mutect2, varscan2
- VWDE | c.4765C>T p.R1589C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs1004135106; called by muse, mutect2, varscan2
- ZDHHC5 | c.1395T>A p.N465K | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54705496; called by muse, mutect2, varscan2
- ABCB4 | c.2025A>T p.Q675H | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABHD17C | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 92/314 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ADAR | c.3166T>G p.F1056V | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF4 | c.1922_1923dup p.A642Mfs*19 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- ALG10 | c.1253T>C p.F418S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD3 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- COL9A2 | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 132/677 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HR | c.1426A>G p.S476G | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKI67 | c.7437G>T p.K2479N | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- NASP | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NDRG3 | c.992C>A p.S331* (on ENST00000349004 / NM_032013.4; = p.S319* on NM_022477.4) | Nonsense Mutation (SNP) | VAF 83/208 reads (40%) | called by muse, mutect2, varscan2
- NECAB2 | c.1091C>A p.T364K | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PLA2G4A | c.1236C>A p.S412R | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- POU6F2 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R11 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PREX1 | c.3992T>A p.L1331Q | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PREX1 | c.3064A>C p.I1022L | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PTPRE | c.1317G>T p.M439I | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PTPRQ | c.3732T>G p.N1244K (on ENST00000616559; = p.N1202K on NM_001145026.2) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PXT1 | c.82T>G p.S28A | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- RAB3IL1 | c.735A>C p.E245D | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAP30BP | c.763A>G p.S255G | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- SLC11A2 | c.922A>T p.R308* (on ENST00000394904 / NM_001379455.1; = p.R279* on NM_000617.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2, varscan2
- SLC16A13 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 123/491 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SYNRG | c.3585T>A p.S1195R | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCHH | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TEX13A | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THOC5 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- TMEM132D | c.2516G>C p.G839A | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- UACA | c.2072A>C p.K691T | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- UGT2A3 | c.1083_1084+2delinsA p.X361_splice | Splice Site (DEL) | VAF 21/50 reads (42%) | called by pindel, varscan2*
- ULK3 | c.1403-2A>T p.X468_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2
- ZFHX3 | c.10285dup p.R3429Pfs*2 | Frame Shift Ins (INS) | VAF 30/179 reads (17%) | called by mutect2, pindel, varscan2
- ZNF518A | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ZNF646 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF875 | c.1687_1707del p.Q564_R570del | In Frame Del (DEL) | VAF 11/97 reads (11%) | called by mutect2, pindel, varscan2
- ACTN2 | c.1704G>A p.A568= | Silent (SNP) | VAF 76/346 reads (22%) | catalogued as rs369560444; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- AQP8 | c.336G>A p.P112= | Silent (SNP) | VAF 47/202 reads (23%) | catalogued as rs199899879, COSV54846031; called by muse, mutect2, varscan2
- CNST | c.726A>G p.Q242= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- LAMB4 | c.4035C>T p.I1345= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- NAA25 | c.645C>A p.V215= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, varscan2
- NUDT13 | c.189A>G p.A63= | Silent (SNP) | VAF 46/207 reads (22%) | called by muse, mutect2, varscan2
- OCSTAMP | c.333C>T p.P111= | Silent (SNP) | VAF 56/294 reads (19%) | called by muse, mutect2, varscan2
- OR4E2 | c.288C>T p.N96= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs376296410; called by muse, mutect2, varscan2
- PCLO | c.3096T>C p.D1032= | Silent (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- PKLR | c.663C>T p.D221= | Silent (SNP) | VAF 108/525 reads (21%) | catalogued as rs761145518, COSV61360475; called by muse, mutect2, varscan2
- PRSS1 | c.540C>A p.T180= | Silent (SNP) | VAF 99/730 reads (14%) | called by muse, mutect2, varscan2
- RPTOR | c.2715G>A p.R905= | Silent (SNP) | VAF 65/278 reads (23%) | called by muse, mutect2, varscan2
- STX4 | c.270C>T p.I90= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1567388424; called by muse, mutect2, varscan2
- VCAN | c.3858T>C p.P1286= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- ZNF587 | c.624A>G p.G208= | Silent (SNP) | VAF 80/585 reads (14%) | called by muse, mutect2, varscan2
- AC024940.1 | n.5572A>G | RNA (SNP) | VAF 3/24 reads (13%) | called by mutect2, varscan2
- DYNC1H1 | c.12902+10T>C | Intron (SNP) | VAF 135/429 reads (31%) | called by muse, mutect2, varscan2
- PARP6 | c.*201C>T | 3'UTR (SNP) | VAF 65/274 reads (24%) | catalogued as rs1016685743; called by muse, mutect2, varscan2
- TRAPPC2L | c.375-17G>A | Intron (SNP) | VAF 49/242 reads (20%) | called by muse, mutect2, varscan2
- TSHZ2 | c.41-67856_41-67853del | Intron (DEL) | VAF 38/169 reads (22%) | called by mutect2, pindel, varscan2
